Somatic mutation profile of tumor specimen TCGA-D1-A176-01A (aliquot TCGA-D1-A176-01A-11D-A12J-09) from TCGA case TCGA-D1-A176, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.1 years (24,521 days).
Specimen TCGA-D1-A176-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c9764bf-bd04-47cd-ba4b-8ed3030e1440.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A176-10A (Blood Derived Normal), aliquot TCGA-D1-A176-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ff1ea88-b8c3-4d31-8283-cb3d8bdabb68

The open-access MAF lists 493 somatic variants for this specimen: 385 protein-altering or splice-affecting, 100 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 100, Frame Shift Del 66, Frame Shift Ins 23, Nonsense Mutation 20, Splice Site 13, In Frame Del 5, Splice Region 5, Intron 5, 3'Flank 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 53/190 reads (28%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- BRWD3 | c.3718C>T p.R1240* | Nonsense Mutation (SNP) | VAF 7/194 reads (4%) | catalogued as rs878853055, COSV64743451; ClinVar: likely pathogenic; called by muse, mutect2
- CACNA1A | c.3544del p.L1182Sfs*8 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1376_1378del p.K459del (on ENST00000521381 / NM_181523.3; = p.K189del on NM_181504.4) | In Frame Del (DEL) | VAF 19/54 reads (35%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- A2ML1 | c.2898G>A p.M966I | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55299422; called by muse, mutect2
- ABCD1 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV54388175; called by muse, mutect2, varscan2
- ABHD4 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777901042, COSV53530827; called by muse, mutect2, varscan2
- ABL2 | c.1535del p.P512Lfs*7 (on ENST00000502732 / NM_007314.4; = p.P497Lfs*7 on NM_005158.5) | Frame Shift Del (DEL) | VAF 57/316 reads (18%) | catalogued as rs753365868, COSV61019281; called by mutect2, pindel, varscan2
- ABLIM3 | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 8/235 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV58649310; called by muse, mutect2
- AC098582.1 | c.331G>T p.G111W | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV52023541, COSV52025553; called by muse, mutect2
- AC100868.1 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs775066233, COSV51840918; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 68/190 reads (36%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 80/292 reads (27%) | catalogued as COSV65879385; called by mutect2, pindel, varscan2
- ADCY5 | c.2641G>A p.V881M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs758708718, COSV59205184; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 46/138 reads (33%) | catalogued as rs772825390; called by mutect2, pindel, varscan2
- AGBL1 | c.1897T>C p.F633L | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66874838; called by muse, mutect2, varscan2
- ALKBH1 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53661520; called by muse, mutect2, varscan2
- AMOT | c.2118-1G>T p.X706_splice (on ENST00000371959 / NM_001113490.1; = p.X297_splice on NM_133265.3) | Splice Site (SNP) | VAF 22/552 reads (4%) | catalogued as COSV59069038; called by muse, mutect2
- ANO1 | c.2251C>A p.L751M | Missense Mutation (SNP) | VAF 99/288 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62450900; called by muse, mutect2, varscan2
- APCDD1 | c.1064G>T p.R355M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62372888, COSV62373492; called by muse, mutect2, varscan2
- ARAP3 | c.2528del p.P843Qfs*72 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs1286143522; called by mutect2, pindel
- ARHGAP21 | c.4040C>A p.P1347H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57611764; called by muse, mutect2, varscan2
- ARL6IP5 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377650671; called by muse, mutect2, varscan2
- ARMC1 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52534995; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 164/706 reads (23%) | catalogued as rs761154268; called by mutect2, varscan2
- ATF6B | c.834G>A p.V278= | Splice Region (SNP) | VAF 45/119 reads (38%) | catalogued as COSV64352762; called by muse, mutect2, varscan2
- ATG10 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 97/244 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV56433524; called by muse, mutect2, varscan2
- ATP1B4 | c.27G>T p.R9S | Missense Mutation (SNP) | VAF 97/244 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV54311102, COSV54315336; called by muse, mutect2, varscan2
- ATP2B2 | c.2759C>T p.T920M (on ENST00000352432; = p.T886M on NM_001683.5) | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs368058047; called by muse, mutect2, varscan2
- ATP2C1 | c.2487+2T>C p.X829_splice | Splice Site (SNP) | VAF 96/249 reads (39%) | catalogued as COSV60763375; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 38/90 reads (42%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATRN | c.2933C>T p.T978M | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53527184; called by muse, mutect2, varscan2
- BAZ1B | c.4396G>T p.G1466W | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as COSV59994961; called by muse, mutect2, varscan2
- BEND2 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 17/557 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66215495, COSV66217499; called by muse, mutect2
- BIVM-ERCC5 | c.2620C>A p.R874S | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV63247652; called by muse, mutect2, varscan2
- BMT2 | c.916A>G p.K306E | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV51781462; called by muse, mutect2
- BMX | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.253); catalogued as COSV59593963; called by muse, mutect2, varscan2
- BRAT1 | c.2221G>T p.G741C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV61397481; called by muse, mutect2, varscan2
- BZW2 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV51757978; called by muse, mutect2, varscan2
- C1QTNF6 | c.237_238insG p.P80Afs*6 | Frame Shift Ins (INS) | VAF 31/88 reads (35%) | catalogued as COSV99742447; called by mutect2, pindel, varscan2
- C20orf96 | c.397A>G p.I133V (on ENST00000360321 / NM_153269.3; = p.I132V on NM_080571.1) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs947621657, COSV64404733; called by muse, mutect2, varscan2
- C6orf120 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as rs774284336, COSV59324597; called by muse, mutect2, varscan2
- CACNA1E | c.6326C>T p.A2109V (on ENST00000367573 / NM_001205293.3; = p.A2066V on NM_000721.4) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.091); catalogued as COSV62432290; called by muse, mutect2, varscan2
- CACNA1G | c.4778A>G p.Y1593C | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1057521306, COSV61740925; ClinVar: uncertain significance; called by muse, mutect2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CADM2 | c.454A>G p.K152E (on ENST00000407528 / NM_001167674.2; = p.K154E on NM_153184.4) | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67407852; called by muse, mutect2
- CAMTA1 | c.1521G>T p.M507I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.006); catalogued as COSV57930226; called by muse, mutect2, varscan2
- CATSPER4 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 83/182 reads (46%) | catalogued as rs1362782128, COSV58793969; called by muse, mutect2, varscan2
- CBLL2 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.298); catalogued as COSV60370454; called by muse, mutect2, varscan2
- CCDC85A | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV68155907; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 31/113 reads (27%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD70 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs750046562, COSV55567348; called by muse, mutect2, varscan2
- CD96 | c.1498A>G p.T500A (on ENST00000283285 / NM_198196.3; = p.T484A on NM_005816.5) | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV51912605; called by muse, mutect2, varscan2
- CDCA7L | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs757664469, COSV60944190; called by muse, mutect2, varscan2
- CEACAM18 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV67284351; called by muse, mutect2, varscan2
- CEP170 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 44/796 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs775792506, COSV60515631; called by muse, mutect2
- CFHR5 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 80/427 reads (19%) | catalogued as COSV56829614; called by muse, mutect2, varscan2
- CHD4 | c.5600G>A p.R1867Q (on ENST00000357008 / NM_001363606.2; = p.R1877Q on NM_001273.5) | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1490981256, COSV58897063; called by muse, mutect2
- CHRM3 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756038537, COSV55081705; called by muse, mutect2, varscan2
- CIC | c.4483G>A p.A1495T | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV50675805; called by muse, mutect2, varscan2
- CIP2A | c.1274-1C>T p.X425_splice | Splice Site (SNP) | VAF 81/225 reads (36%) | catalogued as COSV55421674; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | catalogued as rs752250702; called by mutect2, varscan2
- COL15A1 | c.2467G>T p.G823W | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66649062, COSV66649894; called by muse, mutect2, varscan2
- COL18A1 | c.3911G>C p.G1304A (on ENST00000359759 / NM_130444.3; = p.G1069A on NM_030582.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV60594293; called by muse, mutect2, varscan2
- COL4A6 | c.1830del p.G611Afs*127 | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | catalogued as rs771066852; called by mutect2, pindel, varscan2
- COLGALT2 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 99/442 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747416514, COSV62298592; called by muse, mutect2, varscan2
- COQ8B | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV54577710; called by muse, mutect2, varscan2
- CSDE1 | c.2208G>A p.W736* (on ENST00000358528 / NM_001007553.3; = p.W705* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 58/128 reads (45%) | catalogued as COSV54762091; called by muse, mutect2, varscan2
- CSDE1 | c.212T>G p.F71C | Missense Mutation (SNP) | VAF 155/389 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54762107; called by muse, mutect2, varscan2
- CST4 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 102/323 reads (32%) | catalogued as rs767756120; called by mutect2, pindel, varscan2
- CUBN | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs575021189, COSV64707019; called by muse, mutect2, varscan2
- CWF19L1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as COSV100821480, COSV62499871; called by muse, mutect2, varscan2
- DCBLD2 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs562186974, COSV58793607; called by muse, mutect2
- DDX5 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV56751627; called by muse, mutect2, varscan2
- DEFB110 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 10/236 reads (4%) | catalogued as COSV64485046; called by muse, mutect2
- DHX9 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 24/473 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1049265, COSV62360267; called by muse, mutect2
- DNAH1 | c.4673C>A p.P1558H | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161551826, COSV70237217; called by muse, mutect2, varscan2
- DNAH8 | c.11914G>A p.E3972K | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as COSV59475841; called by muse, mutect2
- DNAJB13 | c.342del p.F114Lfs*8 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs753043871; called by mutect2, pindel, varscan2
- DOCK2 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56958660, COSV56967914; called by muse, mutect2, varscan2
- DPY19L2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1478776218, COSV60541920; called by muse, mutect2, varscan2
- DR1 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV64725888; called by muse, mutect2, varscan2
- DSG3 | c.898A>G p.N300D | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57130084; called by muse, mutect2, varscan2
- DST | c.14819A>T p.N4940I (on ENST00000361203 / NM_001374722.1; = p.N2528I on NM_015548.5) | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV55043179; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 30/83 reads (36%) | catalogued as rs769175197; called by mutect2, varscan2
- EP400 | c.7859C>T p.S2620L | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1381049267, COSV57774212; called by muse, mutect2
- EPB41L2 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764887205, COSV61359489; called by muse, mutect2, varscan2
- EPHB6 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101236006, COSV67421111; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 61/203 reads (30%) | catalogued as rs756461692; called by mutect2, varscan2
- ETV3L | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs202076672; called by muse, mutect2, varscan2
- EYA2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760779973, COSV57951398; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 77/232 reads (33%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 53/162 reads (33%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM110B | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752249974, COSV64066617; called by muse, mutect2, varscan2
- FAM91A1 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 98/244 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58240125; called by muse, mutect2, varscan2
- FAR2 | c.529dup p.I177Nfs*3 | Frame Shift Ins (INS) | VAF 94/290 reads (32%) | catalogued as rs757443519; called by mutect2, varscan2
- FARSA | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV53368800; called by muse, mutect2
- FAT1 | c.6079C>T p.R2027C | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs199867416; called by muse, mutect2, varscan2
- FAT3 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs200065507; called by muse, mutect2, varscan2
- FBN2 | c.7586C>T p.T2529I | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs780729130, COSV52547740; called by muse, mutect2, varscan2
- FBXL3 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV62919430; called by muse, mutect2, varscan2
- FBXO38 | c.2986G>A p.E996K (on ENST00000340253 / NM_205836.3; = p.E921K on NM_030793.5) | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs1399618526, COSV57031796; called by muse, mutect2, varscan2
- FCGBP | c.5930C>T p.A1977V | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as rs1353757348, COSV55457264; called by muse, mutect2, varscan2
- FFAR3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs755812436, COSV59908994; called by muse, mutect2, varscan2
- FGF5 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1489152100, COSV56891761; called by muse, mutect2, varscan2
- FKBP3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as rs964893414, COSV53534005; called by muse, mutect2
- FLCN | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53263778; called by muse, mutect2, varscan2
- FLNC | c.4457-1G>T p.X1486_splice | Splice Site (SNP) | VAF 26/57 reads (46%) | catalogued as rs1404524040, COSV57966128; called by muse, mutect2, varscan2
- FLNC | c.4627C>T p.R1543W | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745648230, COSV57951936, COSV57962032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC3B | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.851); catalogued as COSV61050720; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- G6PC2 | c.202A>G p.N68D | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56373703; called by muse, mutect2, varscan2
- GIN1 | c.169A>G p.R57G | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV67537834; called by muse, mutect2, varscan2
- GLB1 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.274); catalogued as COSV56568451; called by muse, varscan2
- GOLGA3 | c.4021A>G p.M1341V | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1201962520, COSV52645230; called by muse, mutect2, varscan2
- GOT1L1 | c.870del p.N291Tfs*24 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | catalogued as rs768946390; called by mutect2, pindel, varscan2
- GPAT2 | c.2151G>A p.E717= | Splice Region (SNP) | VAF 26/79 reads (33%) | catalogued as COSV64004027; called by muse, mutect2, varscan2
- GPR32 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 156/355 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.036); catalogued as rs1402396520, COSV54515781; called by muse, mutect2, varscan2
- GPR50 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV54443366; called by muse, mutect2, varscan2
- GRHL2 | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV52555677; called by muse, mutect2, varscan2
- HAP1 | c.1813A>G p.M605V (on ENST00000310778 / NM_001367460.1; = p.M553V on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs782807150, COSV57881055; called by muse, mutect2, varscan2
- HDAC10 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450464439, COSV50592740; called by muse, mutect2, varscan2
- HDAC9 | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV67785193; called by muse, mutect2, varscan2
- HEPACAM | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as rs777817159, COSV53430237; called by muse, mutect2, varscan2
- HIPK4 | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV52526248; called by muse, mutect2, varscan2
- HNRNPH1 | c.*1G>A | Splice Site (SNP) | VAF 29/98 reads (30%) | catalogued as COSV61488918; called by muse, mutect2, varscan2
- HSD17B11 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64155425; called by muse, mutect2, varscan2
- HTRA4 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV56761433; called by muse, mutect2
- IGSF10 | c.2707T>C p.F903L | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1466122804, COSV56792553; called by muse, mutect2, varscan2
- IGSF8 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58757843; called by muse, mutect2, varscan2
- IL17RA | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1236554644, COSV60056659; called by muse, mutect2, varscan2
- INSC | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1265431156, COSV65413459; called by muse, mutect2, varscan2
- ITGA9 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs764240180, COSV53253994; called by muse, mutect2, varscan2
- JPH3 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs757955234, COSV52474663; called by muse, mutect2, varscan2
- KBTBD12 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59682186; called by muse, mutect2, varscan2
- KBTBD2 | c.1282C>A p.H428N | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV58364439; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNH2 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.418); catalogued as COSV51232592; called by muse, mutect2, varscan2
- KCNH2 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV51211671; called by muse, mutect2, varscan2
- KCNH2 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs149381387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ5 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 72/177 reads (41%) | catalogued as rs1422613944, COSV57971669; called by muse, varscan2
- KIFC1 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 65/177 reads (37%) | catalogued as COSV65728901; called by muse, mutect2, varscan2
- KIRREL1 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 10/313 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as rs1406099516, COSV63291898; called by muse, mutect2
- KLHL20 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52945461; called by muse, mutect2, varscan2
- KLHL36 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs746406205, COSV50718625; called by muse, mutect2, varscan2
- KMT2B | c.7145G>A p.W2382* | Nonsense Mutation (SNP) | VAF 67/168 reads (40%) | catalogued as COSV55870548; called by muse, mutect2, varscan2
- KMT2B | c.8100G>C p.K2700N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53076912; called by muse, mutect2, varscan2
- KMT2C | c.10418C>A p.P3473Q | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as COSV51508907, COSV51521913; called by muse, mutect2, varscan2
- LAMA3 | c.2839C>T p.R947W | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs924773568, COSV58082014; called by muse, mutect2, varscan2
- LHFPL5 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 11/360 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64177257, COSV64178813; called by muse, mutect2
- LMNA | c.1892dup p.S632Qfs*72 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs770335541; called by mutect2, pindel, varscan2
- LNPEP | c.2882A>G p.Y961C | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs1483300569, COSV51481836; called by muse, mutect2, varscan2
- LOXL4 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV53259603; called by muse, mutect2, varscan2
- LRIG1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV56249083; called by muse, mutect2, varscan2
- LRP1B | c.7003A>G p.T2335A | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67245817, COSV67279840; called by muse, mutect2
- LRRC7 | c.140G>A p.G47D (on ENST00000651989 / NM_001370785.2; = p.G14D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV50645009; called by muse, mutect2, varscan2
- LSM8 | c.72+1G>A p.X24_splice | Splice Site (SNP) | VAF 119/406 reads (29%) | catalogued as COSV50800744; called by muse, mutect2, varscan2
- MAGEC1 | c.1855del p.E619Rfs*11 | Frame Shift Del (DEL) | VAF 18/139 reads (13%) | catalogued as COSV53575459; called by mutect2, pindel, varscan2
- MAP3K15 | c.3295G>T p.V1099L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV58839848; called by mutect2, varscan2
- MAU2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53238526; called by muse, mutect2, varscan2
- MAVS | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV63927693; called by muse, mutect2, varscan2
- MET | c.3751G>A p.A1251T | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59270177; called by muse, mutect2, varscan2
- MFN2 | c.2051G>A p.C684Y | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52425874; called by muse, mutect2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | catalogued as rs750307488; called by mutect2, varscan2
- MTMR11 | c.653C>T p.T218M (on ENST00000439741 / NM_001145862.2; = p.T146M on NM_181873.3) | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs368805416; called by muse, mutect2
- MTR | c.3242G>A p.C1081Y | Missense Mutation (SNP) | VAF 81/457 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63966487; called by muse, mutect2, varscan2
- MUC16 | c.22282C>T p.P7428S | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1182723102, COSV67449473; called by muse, mutect2, varscan2
- MYBL2 | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as COSV53834149; called by muse, mutect2, varscan2
- MYH3 | c.692T>C p.F231S | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV56870656; called by muse, mutect2, varscan2
- MYO16 | c.352A>G p.N118D | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.818); catalogued as COSV51820983; called by muse, mutect2, varscan2
- NCOR2 | c.6760A>G p.M2254V | Missense Mutation (SNP) | VAF 116/287 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as COSV62305386; called by muse, mutect2, varscan2
- NDRG3 | c.199+1G>T p.X67_splice (on ENST00000349004 / NM_032013.4; = p.X55_splice on NM_022477.4) | Splice Site (SNP) | VAF 72/189 reads (38%) | catalogued as COSV62423778; called by muse, mutect2, varscan2
- NELFA | c.490G>A p.A164T (on ENST00000542778; = p.A153T on NM_005663.5) | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs751635541, COSV61608853; called by muse, mutect2, varscan2
- NFKBIL1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs544896018, COSV65990464; called by muse, mutect2, varscan2
- NHSL2 | c.386G>A p.R129Q (on ENST00000510661; = p.R495Q on NM_001013627.2) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762819482, COSV65452490; called by muse, mutect2, varscan2
- NKX2-3 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60729259; called by muse, mutect2, varscan2
- NOA1 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51735783; called by muse, mutect2, varscan2
- NOTCH4 | c.4795G>T p.E1599* | Nonsense Mutation (SNP) | VAF 35/110 reads (32%) | catalogued as COSV66679511, COSV66684275; called by muse, mutect2, varscan2
- NOX3 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs149980019; called by muse, mutect2, varscan2
- NPAP1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as rs1195117251, COSV61508177, COSV61513035; called by muse, mutect2, varscan2
- NPAS3 | c.2626G>A p.V876M (on ENST00000356141 / NM_001164749.2; = p.V844M on NM_022123.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as rs1166511283, COSV60865424; called by muse, mutect2
- NRK | c.4244T>C p.L1415P | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54608086; called by muse, mutect2, varscan2
- NSUN2 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 25/203 reads (12%) | catalogued as COSV52957453; called by muse, mutect2, varscan2
- NTNG2 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62369116; called by muse, mutect2, varscan2
- NUMA1 | c.4468C>T p.R1490C | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs778315290, COSV61191693; called by muse, mutect2, varscan2
- NUP214 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 74/191 reads (39%) | catalogued as COSV63913459; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 47/217 reads (22%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1Q1 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 109/275 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52919289; called by muse, mutect2, varscan2
- OR2G3 | c.186dup p.L63Sfs*14 | Frame Shift Ins (INS) | VAF 133/805 reads (17%) | catalogued as COSV60682833; called by mutect2, pindel, varscan2
- OR4A5 | c.791C>G p.T264S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV60524954; called by muse, mutect2, varscan2
- OR5T2 | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs781192424, COSV57591193; called by muse, mutect2, varscan2
- OR5V1 | c.548del p.P183Lfs*3 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as COSV65829062; called by mutect2, pindel, varscan2
- ORC6 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 64/147 reads (44%) | catalogued as COSV54479632; called by muse, mutect2, varscan2
- PACSIN3 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs147818380; called by muse, mutect2, varscan2
- PAF1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 174/403 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372480955; called by muse, mutect2, varscan2
- PAPPA2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs758781900, COSV62773172; called by muse, mutect2
- PARP12 | c.2038T>A p.S680T | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs775074541, COSV54937501; called by muse, varscan2
- PARP4 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs758277432, COSV67964417; called by muse, mutect2
- PARP4 | c.2225C>A p.T742N | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV67964518; called by muse, mutect2, varscan2
- PARP6 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV53005347; called by muse, mutect2, varscan2
- PASK | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs199606444, COSV52149738; called by muse, mutect2, varscan2
- PCDH9 | c.3141G>A p.S1047= (on ENST00000377865 / NM_203487.3; = p.S1013= on NM_020403.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 12/100 reads (12%) | catalogued as rs776019485, COSV60594482; called by muse, mutect2, varscan2
- PCDHGB7 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV53998269; called by muse, mutect2, varscan2
- PCSK2 | c.1747del p.V583Cfs*2 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as COSV99359260; called by mutect2, pindel, varscan2
- PDAP1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 138/393 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV53162663; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 150/204 reads (74%) | catalogued as rs759495724; called by mutect2, varscan2
- PGBD2 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 58/228 reads (25%) | catalogued as rs775887214, COSV61401288; called by muse, mutect2, varscan2
- PGM5 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67169298; called by muse, mutect2, varscan2
- PHF3 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV50345763; called by muse, mutect2, varscan2
- PIAS1 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs1333849976, COSV51038844; called by muse, mutect2, varscan2
- PIP5KL1 | c.1003C>A p.L335M (on ENST00000388747 / NM_001135219.2; = p.L132M on NM_173492.1) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV55945570; called by muse, mutect2, varscan2
- PJA1 | c.1258G>A p.G420S (on ENST00000361478 / NM_145119.4; = p.G232S on NM_022368.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs772473232, COSV100824825; called by mutect2, varscan2
- PKHD1L1 | c.6563dup p.S2190Ifs*39 | Frame Shift Ins (INS) | VAF 24/104 reads (23%) | catalogued as rs772426616; called by mutect2, varscan2
- PKP3 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV58990382; called by muse, mutect2, varscan2
- PLA2G2E | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553164440, COSV64290376, COSV64290551; called by muse, mutect2
- PLEKHA6 | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 84/355 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201509011, COSV55340943; called by muse, mutect2, varscan2
- PLEKHG3 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs768632545, COSV55984400; called by muse, mutect2
- PMP22 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56603605; called by muse, mutect2, varscan2
- PNPT1 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV53180433; called by muse, mutect2, varscan2
- PODN | c.1732C>T p.Q578* (on ENST00000395871; = p.Q530* on NM_153703.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as rs1186777121, COSV57017909; called by muse, mutect2, varscan2
- POU4F1 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65885142; called by muse, mutect2, varscan2
- PRICKLE3 | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV66235729; called by muse, mutect2, varscan2
- PRKCD | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57852064; called by muse, mutect2
- PRPF40B | c.874G>A p.V292I (on ENST00000380281; = p.V286I on NM_012272.3) | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.336); catalogued as rs952455047, COSV56058001; called by muse, mutect2, varscan2
- PRR5 | c.1153C>T p.Q385* (on ENST00000336985 / NM_181333.4; = p.Q376* on NM_015366.4) | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV50064071; called by muse, mutect2, varscan2
- PRRX1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as rs761253714, COSV53410992; called by muse, mutect2, varscan2
- PSD | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV50064933; called by muse, mutect2, varscan2
- PSMC1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs778285380, COSV54322290; called by muse, mutect2, varscan2
- PSMD1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs1194484873, COSV58077186; called by muse, mutect2, varscan2
- PTPRN | c.356del p.P119Qfs*81 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | catalogued as rs759562798; called by mutect2, pindel, varscan2
- PXDN | c.2446C>T p.H816Y | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53247277, COSV99414811; called by muse, mutect2, varscan2
- RAB15 | c.490del p.R164Vfs*2 (on ENST00000533601 / NM_001308154.2; = p.V208Sfs*10 on NM_198686.3) | Frame Shift Del (DEL) | VAF 45/166 reads (27%) | catalogued as COSV50825673, COSV99962069; called by mutect2, pindel, varscan2
- RABEP2 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs747271462, COSV62871228; called by muse, mutect2, varscan2
- RALGAPA1 | c.1826del p.N609Ifs*2 | Frame Shift Del (DEL) | VAF 47/128 reads (37%) | catalogued as rs748033282; called by mutect2, varscan2
- RANBP6 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs769632096, COSV52391818; called by muse, mutect2, varscan2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs760908242; called by mutect2, varscan2
- REC8 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.922); catalogued as COSV61018640; called by muse, mutect2, varscan2
- RGL3 | c.1100+1G>T p.X367_splice | Splice Site (SNP) | VAF 53/104 reads (51%) | catalogued as COSV63387283; called by muse, mutect2, varscan2
- RGS20 | c.319del p.L107Cfs*41 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs747974681; called by mutect2, pindel
- RHOC | c.544C>A p.R182S | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53518424, COSV53519458; called by muse, mutect2, varscan2
- RIF1 | c.4603C>T p.R1535W | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184980711, COSV54625199; called by muse, mutect2, varscan2
- RNF122 | c.5A>G p.H2R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV56360188; called by muse, mutect2, varscan2
- RNF213 | c.14192G>A p.R4731Q | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758730525, COSV60410155; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 78/123 reads (63%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RP1L1 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1362551155, COSV66752957; called by muse, mutect2, varscan2
- RPP25L | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52409283; called by muse, mutect2, varscan2
- RTEL1 | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58902456; called by muse, mutect2, varscan2
- RTN4R | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1169647613; called by muse, mutect2
- RUBCN | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs202160344, COSV56363580; called by muse, mutect2, varscan2
- RXFP3 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs138975968, COSV100347578; called by muse, mutect2, varscan2
- SACS | c.8728A>T p.N2910Y | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66547440; called by muse, mutect2
- SAFB2 | c.2471del p.G824Afs*8 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs759920279; called by mutect2, pindel
- SAMM50 | c.936+2T>G p.X312_splice | Splice Site (SNP) | VAF 67/154 reads (44%) | catalogued as COSV63110795; called by muse, mutect2, varscan2
- SCARB2 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53670722; called by muse, mutect2
- SEC63 | c.1586del p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 59/160 reads (37%) | catalogued as rs758487924; called by mutect2, varscan2
- SENP1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV50307900; called by muse, mutect2
- SETX | c.6860G>A p.R2287Q | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1466743041, COSV56395858; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 34/137 reads (25%) | catalogued as rs746556543; called by mutect2, varscan2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 13/19 reads (68%) | catalogued as COSV53462966; called by mutect2, pindel, varscan2
- SLC12A9 | c.2000C>A p.P667H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV51937581; called by muse, mutect2, varscan2
- SLC17A4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV64957421; called by muse, mutect2, varscan2
- SLC22A4 | c.1520del p.F507Sfs*7 | Frame Shift Del (DEL) | VAF 87/262 reads (33%) | catalogued as rs72552721; called by mutect2, pindel, varscan2
- SLC2A14 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs780109041, COSV61586144, COSV61588360; called by muse, mutect2, varscan2
- SLC30A7 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.954); catalogued as rs1254729570, COSV63018811; called by muse, mutect2
- SLC38A5 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs782383746, COSV58335726; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC9A3 | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV53805823; called by muse, mutect2, varscan2
- SMPD4 | c.2142+2T>C p.X714_splice (on ENST00000409031 / NM_017951.4; = p.X685_splice on NM_017751.4) | Splice Site (SNP) | VAF 30/71 reads (42%) | catalogued as COSV60083242; called by muse, mutect2, varscan2
- SMURF2 | c.91+1G>A p.X31_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as rs1555689073, COSV52320351; called by muse, mutect2
- SNRNP70 | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV55507602; called by muse, varscan2
- SOS1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV67677878; called by muse, mutect2, varscan2
- SPTAN1 | c.6749G>A p.R2250H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs201693154, COSV63990084; called by muse, mutect2, varscan2
- SPTB | c.5363C>T p.T1788M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167836684, COSV67630245; called by muse, mutect2, varscan2
- SPTBN4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs377149796; called by muse, mutect2, varscan2
- SSTR4 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as rs1441694981, COSV54800313; called by muse, mutect2, varscan2
- SULT1C2 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV52267474; called by muse, mutect2, varscan2
- SUPV3L1 | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV62846491; called by muse, mutect2, varscan2
- TACR3 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.141); catalogued as COSV59209385; called by muse, mutect2
- TANC2 | c.486C>A p.C162* | Nonsense Mutation (SNP) | VAF 11/357 reads (3%) | catalogued as COSV67342227; called by muse, mutect2
- TASOR2 | c.2801A>T p.N934I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV60169869; called by muse, mutect2
- TCAF2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV62052976; called by muse, mutect2, varscan2
- TCEA2 | c.72G>A p.A24= | Splice Region (SNP) | VAF 7/33 reads (21%) | catalogued as rs1323978087, COSV58659611; called by muse, mutect2, varscan2
- TCEAL3 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 301/762 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV54581560; called by muse, mutect2, varscan2
- TCF20 | c.5842G>A p.A1948T | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs539500058, COSV59496514; called by muse, mutect2, varscan2
- TENM4 | c.2755G>T p.G919W | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV53675060; called by muse, mutect2, varscan2
- TESK2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs545470915, COSV59150417; called by muse, mutect2, varscan2
- TESK2 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs200465813; called by muse, mutect2, varscan2
- TEX10 | c.430C>A p.H144N | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66518967; called by muse, mutect2, varscan2
- TEX13B | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774841881, COSV57202120, COSV57204011; called by muse, mutect2, varscan2
- TGFBR1 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766157497, COSV66627143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs773353392, COSV51516733; called by muse, mutect2, varscan2
- THBD | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs1370115907, COSV65703268; called by muse, mutect2
- TIMELESS | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57515706; called by muse, mutect2
- TLR6 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs55963748, COSV67935866; called by muse, mutect2, varscan2
- TMEM132B | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54772346; called by muse, mutect2, varscan2
- TMEM38A | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329771060, COSV51818878; called by muse, mutect2, varscan2
- TMEM63C | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 135/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749012437, COSV53601180; called by muse, mutect2, varscan2
- TMPRSS9 | c.1858C>A p.P620T (on ENST00000648592; = p.P586T on NM_182973.2) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60231927; called by muse, mutect2, varscan2
- TP53BP2 | c.1402G>A p.A468T (on ENST00000343537 / NM_001031685.3; = p.A339T on NM_005426.2) | Missense Mutation (SNP) | VAF 36/730 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV59073603; called by muse, mutect2
- TPCN1 | c.157A>G p.S53G | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59241240; called by muse, mutect2, varscan2
- TRAIP | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162978165, COSV58917071; called by muse, mutect2, varscan2
- TRIM33 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 248/659 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV61826262; called by muse, mutect2, varscan2
- TRIML1 | c.1018A>G p.R340G | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60197168; called by muse, mutect2
- TRPM3 | c.2248G>A p.D750N (on ENST00000357533 / NM_001366142.2; = p.D593N on NM_020952.6) | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV62583358; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL11 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs145304541; called by muse, mutect2, varscan2
- TTN | c.21370C>T p.R7124* (on ENST00000591111; = p.R6197* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as rs746136883, COSV59870609; called by muse, mutect2, varscan2
- TTYH3 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1358242885, COSV51863364; called by muse, mutect2, varscan2
- TUBA3C | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV68029758; called by muse, mutect2, varscan2
- TUBGCP6 | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as COSV50592738; called by muse, mutect2, varscan2
- TXNIP | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65221531; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | catalogued as rs760213136; called by mutect2, varscan2
- USO1 | c.1958C>T p.T653I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs759846499, COSV53711180; called by muse, mutect2, varscan2
- USP21 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.084); catalogued as rs1341917803, COSV57091602; called by muse, mutect2, varscan2
- USP34 | c.8422G>T p.V2808F | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV68407447; called by muse, mutect2, varscan2
- UTP6 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs199527189, COSV55576121; called by muse, mutect2, varscan2
- VWF | c.5038C>A p.L1680I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV54636205; called by muse, mutect2, varscan2
- WASHC5 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs976509563, COSV59196844; called by muse, mutect2, varscan2
- WBP1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554067981, COSV51971459; called by muse, mutect2, varscan2
- WDR44 | c.1414A>G p.S472G | Missense Mutation (SNP) | VAF 126/326 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV54169841; called by muse, mutect2, varscan2
- WDR55 | c.1022dup p.G343Rfs*15 | Frame Shift Ins (INS) | VAF 55/138 reads (40%) | catalogued as rs746919573; called by mutect2, varscan2
- WNK2 | c.1981G>A p.V661I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs774069447, COSV52963028; called by muse, mutect2
- ZBTB33 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV58533662; called by muse, mutect2, varscan2
- ZDHHC14 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63078193; called by muse, mutect2, varscan2
- ZFAT | c.2239T>G p.C747G | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64748202; called by muse, mutect2, varscan2
- ZFYVE28 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748075514, COSV52118163; called by muse, mutect2
- ZIM3 | c.588A>C p.E196D | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.348); catalogued as COSV54147162; called by muse, mutect2
- ZNF154 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV70744749; called by muse, mutect2
- ZNF335 | c.1537C>T p.H513Y | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59820628; called by muse, mutect2, varscan2
- ZNF416 | c.257_259del p.E86del | In Frame Del (DEL) | VAF 61/169 reads (36%) | catalogued as rs754413304; called by mutect2, pindel, varscan2
- ZNF609 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58590928; called by muse, mutect2, varscan2
- ZNF672 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.44); catalogued as rs1284395307, COSV60639244; called by muse, mutect2, varscan2
- ZNF683 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 169/457 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV62876052; called by muse, mutect2, varscan2
- ZWINT | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59186457; called by muse, mutect2, varscan2
- ATP11B | c.1113del p.F371Lfs*24 | Frame Shift Del (DEL) | VAF 59/169 reads (35%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.4806del p.R1605Afs*107 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- BEND3 | c.699dup p.T234Hfs*2 | Frame Shift Ins (INS) | VAF 62/170 reads (36%) | called by mutect2, pindel, varscan2
- BEX4 | c.122del p.G41Vfs*40 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- CHST2 | c.723del p.R242Afs*60 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | called by mutect2, pindel, varscan2
- CILK1 | c.1331dup p.N444Kfs*7 (on ENST00000350082 / NM_001375397.1; = p.N437Kfs*7 on NM_014920.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 99/305 reads (32%) | called by mutect2, pindel, varscan2
- CYP2E1 | c.713del p.N238Mfs*5 | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | called by mutect2, pindel, varscan2
- EFR3A | c.429dup p.V144Cfs*13 | Frame Shift Ins (INS) | VAF 42/262 reads (16%) | called by mutect2, pindel, varscan2
- ENHO | c.134_135dup p.E46Lfs*44 | Frame Shift Ins (INS) | VAF 34/90 reads (38%) | called by mutect2, varscan2
- ENTPD8 | c.660del p.I221Sfs*33 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- EPS8L3 | c.818del p.N273Tfs*33 | Frame Shift Del (DEL) | VAF 162/404 reads (40%) | called by mutect2, varscan2
- FOXA2 | c.1103_1104dup p.H369Tfs*41 (on ENST00000377115 / NM_153675.3; = p.H375Tfs*41 on NM_021784.5) | Frame Shift Ins (INS) | VAF 143/408 reads (35%) | called by mutect2, pindel, varscan2
- FRG2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GALNT17 | c.1691del p.G564Afs*116 | Frame Shift Del (DEL) | VAF 42/126 reads (33%) | called by mutect2, pindel, varscan2
- HECTD1 | c.6813del p.F2271Lfs*13 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- IFNL3 | c.491dup p.E165Gfs*48 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | called by mutect2, varscan2
- IMPG1 | c.847del p.I283Sfs*4 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- INSR | c.2489del p.P830Lfs*28 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- KMT2D | c.4444del p.A1482Lfs*24 | Frame Shift Del (DEL) | VAF 50/147 reads (34%) | called by mutect2, pindel, varscan2
- LILRA6 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K14 | c.2335_2337del p.L779del | In Frame Del (DEL) | VAF 25/58 reads (43%) | called by mutect2, pindel, varscan2
- MAPRE2 | c.965del p.P322Rfs*80 | Frame Shift Del (DEL) | VAF 91/242 reads (38%) | called by mutect2, pindel, varscan2
- MGA | c.3744dup p.E1249Rfs*25 | Frame Shift Ins (INS) | VAF 174/329 reads (53%) | called by mutect2, varscan2
- MGAT4A | c.632del p.P211Lfs*8 | Frame Shift Del (DEL) | VAF 67/211 reads (32%) | called by mutect2, pindel, varscan2
- NBEA | c.499del p.M167* | Frame Shift Del (DEL) | VAF 69/212 reads (33%) | called by mutect2, pindel, varscan2
- NHSL2 | c.1923dup p.P642Tfs*44 (on ENST00000510661; = p.P1008Tfs*44 on NM_001013627.2) | Frame Shift Ins (INS) | VAF 21/109 reads (19%) | called by mutect2, varscan2
- PKN2 | c.184dup p.I62Nfs*6 | Frame Shift Ins (INS) | VAF 50/130 reads (38%) | called by mutect2, pindel, varscan2
- PLGRKT | c.183dup p.G62Wfs*13 | Frame Shift Ins (INS) | VAF 52/138 reads (38%) | called by mutect2, varscan2
- POLA1 | c.3158del p.K1053Rfs*25 | Frame Shift Del (DEL) | VAF 58/194 reads (30%) | called by mutect2, varscan2
- POLR2A | c.1862T>C p.I621T | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2
- PRRC2C | c.4891del p.R1631Efs*31 (on ENST00000367742; = p.R1629Efs*31 on NM_015172.4) | Frame Shift Del (DEL) | VAF 48/221 reads (22%) | called by mutect2, pindel, varscan2
- PTPRF | c.5297_5299del p.V1766del | In Frame Del (DEL) | VAF 51/205 reads (25%) | called by pindel, varscan2
- PUS7 | c.96dup p.Q33Tfs*18 | Frame Shift Ins (INS) | VAF 159/437 reads (36%) | called by mutect2, varscan2
- REV3L | c.8133_8134del p.R2711Sfs*7 | Frame Shift Del (DEL) | VAF 82/280 reads (29%) | called by pindel, varscan2
- RNF144A | c.170_172del p.E57del | In Frame Del (DEL) | VAF 54/187 reads (29%) | called by pindel, varscan2
- ROCK2 | c.4040del p.K1347Rfs*21 | Frame Shift Del (DEL) | VAF 82/254 reads (32%) | called by mutect2, pindel, varscan2
- SCLT1 | c.687-3del | Splice Region (DEL) | VAF 43/141 reads (30%) | called by mutect2, pindel, varscan2
- SCYL1 | c.1959+6_1959+7del p.X653_splice | Splice Site (DEL) | VAF 38/143 reads (27%) | called by pindel, varscan2
- SERPIND1 | c.1262dup p.N421Kfs*85 | Frame Shift Ins (INS) | VAF 62/194 reads (32%) | called by mutect2, pindel, varscan2
- SETBP1 | c.1614del p.K538Nfs*17 | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | called by mutect2, pindel, varscan2
- SLCO5A1 | c.663dup p.Y222Lfs*38 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- SLX1A | c.610del p.H204Tfs*6 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- SMARCAL1 | c.212dup p.K72Qfs*7 | Frame Shift Ins (INS) | VAF 33/133 reads (25%) | called by mutect2, pindel, varscan2
- STK11 | c.1010_1011del p.V337Gfs*22 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by pindel, varscan2
- TDRD6 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE3A | c.1725del p.Q576Sfs*39 | Frame Shift Del (DEL) | VAF 89/287 reads (31%) | called by mutect2, pindel, varscan2
- YY1 | c.690dup p.D231Rfs*3 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | called by mutect2, varscan2
- ZBTB20 | c.1727del p.K576Sfs*42 (on ENST00000474710 / NM_001164342.2; = p.K503Sfs*42 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 72/192 reads (38%) | called by mutect2, varscan2
- ZFHX3 | c.6195del p.A2066Hfs*35 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- ZNF777 | c.822del p.G275Afs*39 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- ZNF827 | c.3070dup p.C1024Lfs*12 | Frame Shift Ins (INS) | VAF 29/90 reads (32%) | called by mutect2, pindel, varscan2
- ABCC1 | c.4419G>A p.R1473= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV60695237; called by muse, mutect2, varscan2
- ACSM4 | c.720G>A p.Q240= | Silent (SNP) | VAF 85/210 reads (40%) | catalogued as rs770203103, COSV68069656; called by muse, mutect2, varscan2
- ACTN4 | c.759C>T p.D253= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as rs749219690, COSV53151231; called by muse, varscan2
- ADARB1 | c.768G>T p.G256= | Silent (SNP) | VAF 89/217 reads (41%) | catalogued as COSV62348702; called by muse, mutect2, varscan2
- ANAPC2 | c.1461C>T p.A487= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs553438864, COSV60572612; called by muse, mutect2, varscan2
- ANKS3 | c.588C>T p.D196= | Silent (SNP) | VAF 82/190 reads (43%) | catalogued as rs893564422, COSV58512222; called by muse, varscan2
- AQR | c.1260G>A p.Q420= | Silent (SNP) | VAF 61/167 reads (37%) | catalogued as COSV50057945; called by muse, mutect2, varscan2
- ARHGEF7 | c.612C>A p.S204= (on ENST00000375741 / NM_001113511.2; = p.S26= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 77/174 reads (44%) | catalogued as COSV54552711; called by muse, mutect2, varscan2
- BAZ1B | c.1753T>C p.L585= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV59994971; called by muse, mutect2, varscan2
- BCL2L11 | c.189G>A p.P63= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as rs758731588, COSV58029354; called by muse, mutect2, varscan2
- BOC | c.2766C>T p.L922= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as COSV56358618; called by muse, mutect2, varscan2
- BPTF | c.1209T>C p.L403= | Silent (SNP) | VAF 52/470 reads (11%) | catalogued as COSV58848116; called by muse, mutect2, varscan2
- C11orf24 | c.168C>T p.T56= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV58506713; called by muse, mutect2, varscan2
- C21orf58 | c.798G>A p.L266= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52452032; called by muse, mutect2, varscan2
- C8B | c.990C>T p.Y330= | Silent (SNP) | VAF 64/197 reads (32%) | catalogued as rs753625747, COSV64778056; called by muse, mutect2, varscan2
- C9orf50 | c.612G>A p.S204= | Silent (SNP) | VAF 85/197 reads (43%) | catalogued as rs745405190, COSV65252155; called by muse, mutect2, varscan2
- CAMTA2 | c.1599C>T p.S533= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV100772410, COSV61838645; called by muse, mutect2, varscan2
- CARD9 | c.408G>A p.L136= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV53738324; called by muse, mutect2, varscan2
- CATIP | c.337C>T p.L113= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV56824617; called by muse, mutect2, varscan2
- CDADC1 | c.663G>A p.P221= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs139752988; called by muse, mutect2, varscan2
- CDK13 | c.3087G>A p.K1029= | Silent (SNP) | VAF 65/162 reads (40%) | catalogued as COSV51707081; called by muse, mutect2, varscan2
- CHDH | c.480C>T p.Y160= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs770352293, COSV59460289; called by muse, mutect2
- CLPTM1L | c.540G>T p.A180= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV57993193; called by muse, mutect2
- CPSF1 | c.3696G>A p.S1232= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1403869657, COSV58235209; called by muse, mutect2, varscan2
- DAB2IP | c.2601G>A p.A867= (on ENST00000408936; = p.A839= on NM_032552.3) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs758656943, COSV52269228; called by muse, mutect2
- DDX11 | c.2088C>T p.C696= | Silent (SNP) | VAF 174/535 reads (33%) | catalogued as rs779746853, COSV52502219; called by muse, mutect2, varscan2
- DEPDC7 | c.1287T>C p.I429= (on ENST00000241051 / NM_001077242.2; = p.I420= on NM_139160.2) | Silent (SNP) | VAF 78/210 reads (37%) | catalogued as COSV53809532; called by muse, mutect2, varscan2
- DIDO1 | c.5139C>T p.S1713= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs374372246; called by muse, mutect2, varscan2
- DIS3L2 | c.2526G>T p.V842= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV56064930; called by muse, mutect2, varscan2
- DLGAP1 | c.693G>T p.S231= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV59839457; called by muse, mutect2, varscan2
- DNAH9 | c.10020G>A p.V3340= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV52379377; called by muse, mutect2, varscan2
- DNTT | c.981C>T p.F327= | Silent (SNP) | VAF 117/313 reads (37%) | catalogued as rs771895179, COSV64522868; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.165C>T p.R55= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs986649840, COSV55745846; called by muse, mutect2
- FAM83B | c.942A>G p.A314= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV60927474; called by muse, mutect2
- FBXL12 | c.486C>T p.P162= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs774054910, COSV56114895; called by muse, mutect2, varscan2
- FBXL6 | c.708C>T p.D236= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs1187211145, COSV57353768; called by muse, mutect2, varscan2
- FOXD4L5 | c.237C>T p.G79= | Silent (SNP) | VAF 58/297 reads (20%) | catalogued as COSV66241352; called by muse, mutect2, varscan2
- FRG2C | c.660C>T p.A220= | Silent (SNP) | VAF 144/1022 reads (14%) | called by muse, mutect2, varscan2
- GAS2L1 | c.1005A>G p.P335= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53332127; called by muse, mutect2
- GIMAP4 | c.492G>A p.L164= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV55434926; called by muse, mutect2, varscan2
- GMPR | c.300C>T p.A100= | Silent (SNP) | VAF 23/410 reads (6%) | catalogued as rs758501026, COSV52475739; called by muse, mutect2
- GTF3C3 | c.1206T>C p.L402= | Silent (SNP) | VAF 12/248 reads (5%) | catalogued as COSV55834859; called by muse, mutect2
- HCFC2 | c.1402T>C p.L468= | Silent (SNP) | VAF 65/187 reads (35%) | catalogued as COSV57560616; called by muse, mutect2, varscan2
- HERC2 | c.9222T>C p.G3074= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV55352678; called by muse, mutect2, varscan2
- HIP1R | c.2184C>T p.C728= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs367930717; called by muse, mutect2, varscan2
- HUS1B | c.99C>T p.R33= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1439403326, COSV57862165, COSV57871245; called by muse, mutect2
- IFNA8 | c.228C>A p.A76= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV66505115; called by muse, mutect2, varscan2
- IGLV2-23 | c.273G>A p.T91= | Silent (SNP) | VAF 77/205 reads (38%) | catalogued as rs764898606; called by muse, mutect2, varscan2
- KCNA5 | c.1329C>T p.I443= | Silent (SNP) | VAF 78/205 reads (38%) | catalogued as rs147209278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNE5 | c.24G>A p.R8= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV64508693; called by muse, mutect2
- KCTD8 | c.1386A>G p.Q462= | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as COSV63597640; called by muse, mutect2
- KMT2E | c.4452G>A p.Q1484= | Silent (SNP) | VAF 11/260 reads (4%) | catalogued as COSV57580576; called by muse, mutect2
- LDHD | c.1086G>A p.E362= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV55582146; called by muse, mutect2, varscan2
- LYST | c.7218C>T p.G2406= | Silent (SNP) | VAF 50/311 reads (16%) | catalogued as rs772826541, COSV67714968; called by muse, mutect2, varscan2
- MAP3K14 | c.741C>T p.D247= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs754605998, COSV60925232; called by muse, mutect2, varscan2
- MAP3K6 | c.2628G>A p.S876= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs374817000, COSV58873537; called by muse, mutect2, varscan2
- MAP4K3 | c.1737C>T p.A579= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs759835058, COSV55719263; called by muse, mutect2, varscan2
- MED12 | c.4665G>A p.T1555= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as rs375001801, COSV61357694; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGAT3 | c.912G>A p.L304= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs963481615, COSV57868908; called by muse, mutect2, varscan2
- MTUS2 | c.831C>T p.S277= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs373502341; called by muse, mutect2, varscan2
- MYO10 | c.1518C>A p.I506= | Silent (SNP) | VAF 74/219 reads (34%) | catalogued as COSV72563731; called by muse, mutect2, varscan2
- NRK | c.1794G>A p.V598= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as COSV54608072; called by muse, mutect2, varscan2
- OR56A3 | c.631C>T p.L211= | Silent (SNP) | VAF 14/241 reads (6%) | catalogued as COSV61570197; called by muse, mutect2
- PCSK2 | c.108G>T p.V36= | Silent (SNP) | VAF 47/322 reads (15%) | catalogued as COSV52744462; called by muse, mutect2, varscan2
- PHF1 | c.504A>G p.P168= | Silent (SNP) | VAF 101/224 reads (45%) | catalogued as rs1168695604, COSV65703453; called by muse, mutect2, varscan2
- PIGK | c.639A>G p.E213= | Silent (SNP) | VAF 67/143 reads (47%) | catalogued as COSV63063781; called by muse, mutect2, varscan2
- PIK3C3 | c.873C>A p.A291= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV56285313; called by muse, mutect2, varscan2
- PTGDR2 | c.480G>A p.V160= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV57126454; called by muse, mutect2, varscan2
- PTPN14 | c.108G>A p.T36= | Silent (SNP) | VAF 64/328 reads (20%) | catalogued as rs748318666, COSV65281062; called by muse, mutect2, varscan2
- RBM19 | c.705C>T p.H235= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as COSV55696515, COSV55699135; called by muse, mutect2
- RINL | c.1356C>T p.A452= (on ENST00000591812 / NM_001195833.2; = p.A338= on NM_198445.4) | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as rs1044883027, COSV61575912; called by muse, mutect2
- RNF14 | c.912A>G p.A304= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as COSV61662930; called by muse, mutect2, varscan2
- RUNX3 | c.222C>T p.F74= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs750722272, COSV58246098; called by muse, mutect2, varscan2
- S100A7A | c.249C>T p.A83= | Silent (SNP) | VAF 43/199 reads (22%) | catalogued as rs770816797, COSV61330083; called by muse, mutect2, varscan2
- SCN3A | c.4896A>G p.L1632= | Silent (SNP) | VAF 106/282 reads (38%) | catalogued as COSV51826097; called by muse, mutect2, varscan2
- SENP3 | c.756A>G p.Q252= | Silent (SNP) | VAF 93/202 reads (46%) | catalogued as rs1314958245, COSV53438159; called by muse, mutect2, varscan2
- SGSM1 | c.1323C>T p.S441= | Silent (SNP) | VAF 96/214 reads (45%) | catalogued as rs1360050842, COSV68512108, COSV68514096; called by muse, mutect2, varscan2
- SLC38A10 | c.1968G>A p.A656= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs767597459, COSV55849749; called by muse, mutect2, varscan2
- SLC6A3 | c.1200G>A p.T400= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs199564835, COSV54370092; called by muse, mutect2, varscan2
- SPG7 | c.993C>T p.G331= (on ENST00000268704; = p.G338= on NM_003119.4) | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs576575379, COSV51955190; ClinVar: likely benign; called by muse, mutect2, varscan2
- ST14 | c.864C>T p.H288= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs750492145, COSV53837410; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.432A>G p.S144= | Silent (SNP) | VAF 81/213 reads (38%) | catalogued as rs938179002, COSV52536831; called by muse, mutect2, varscan2
- STRA8 | c.519G>A p.A173= (on ENST00000275764; = p.A151= on NM_182489.2) | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV51963551; called by muse, mutect2
- SYNPO | c.2673C>T p.P891= (on ENST00000394243 / NM_001166208.2; = p.P647= on NM_007286.6) | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs200094717, COSV56941983, COSV56943182; called by muse, mutect2, varscan2
- TAF9B | c.265A>C p.R89= | Silent (SNP) | VAF 120/298 reads (40%) | catalogued as COSV59372486; called by muse, mutect2, varscan2
- TCF25 | c.2004C>T p.D668= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs759038457, COSV54533545; called by muse, mutect2, varscan2
- TCHH | c.1095G>A p.R365= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, varscan2
- TENT4B | c.987T>C p.F329= (on ENST00000561678 / NM_001365323.2; = p.F314= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV62549630; called by muse, mutect2, varscan2
- TEX14 | c.2031G>A p.A677= (on ENST00000240361 / NM_001201457.2; = p.A671= on NM_031272.5) | Silent (SNP) | VAF 103/309 reads (33%) | catalogued as rs142675831; called by muse, mutect2, varscan2
- TJP3 | c.1143G>A p.T381= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs564498611, COSV53663506; called by muse, mutect2, varscan2
- TMEM259 | c.438C>T p.S146= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV52263885; called by muse, mutect2, varscan2
- TMTC4 | c.1122C>T p.C374= (on ENST00000376234 / NM_001350577.2; = p.C393= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as rs759821891, COSV60893783; called by muse, mutect2, varscan2
- TMX4 | c.840G>A p.E280= | Silent (SNP) | VAF 173/449 reads (39%) | catalogued as COSV55682696; called by muse, mutect2, varscan2
- TNRC6A | c.936A>G p.P312= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as COSV59370704; called by muse, mutect2, varscan2
- TP73 | c.1215G>A p.P405= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs201857112, COSV60700182; called by muse, mutect2, varscan2
- TRMT1L | c.2190C>T p.C730= | Silent (SNP) | VAF 58/273 reads (21%) | catalogued as COSV62273666; called by muse, mutect2, varscan2
- TSPYL6 | c.786G>A p.L262= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs372937006, COSV57820929; called by muse, mutect2, varscan2
- TYMS | c.681C>T p.I227= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as COSV51896081; called by muse, mutect2, varscan2
- WDR91 | c.831G>A p.S277= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as rs1288211495, COSV60370781; called by muse, mutect2, varscan2
- ZNF239 | c.1155C>T p.S385= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as COSV60019890; called by muse, mutect2
- DST | c.4296+4583_4296+4585del | Intron (DEL) | VAF 134/362 reads (37%) | catalogued as rs780085037; called by pindel, varscan2
- EMC3-AS1 | chr3:10007501 del TTC | 3'Flank (DEL) | VAF 74/246 reads (30%) | catalogued as rs936959639; called by pindel, varscan2
- NTRK3 | c.1586-38687C>G | Intron (SNP) | VAF 53/136 reads (39%) | catalogued as rs1298389501, COSV58114675, COSV58146479; called by muse, mutect2, varscan2
- PCDHGA9 | c.2424+17del | Intron (DEL) | VAF 30/82 reads (37%) | catalogued as rs759226115; called by mutect2, varscan2
- POLR1E | chr9:37486094 C>T | 5'Flank (SNP) | VAF 36/127 reads (28%) | catalogued as rs754249668, COSV66773168; called by muse, mutect2, varscan2
- S1PR3 | c.-148+222C>T | Intron (SNP) | VAF 39/125 reads (31%) | catalogued as COSV57837499; called by muse, mutect2, varscan2
- SLC16A2 | c.-133C>T | 5'UTR (SNP) | VAF 13/47 reads (28%) | catalogued as COSV52089249; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+512_-12+514del | Intron (DEL) | VAF 59/178 reads (33%) | catalogued as rs762287024; called by mutect2, pindel, varscan2
